Somatic mutation profile of tumor specimen TCGA-GS-A9TZ-01A (aliquot TCGA-GS-A9TZ-01A-11D-A38X-10) from TCGA case TCGA-GS-A9TZ, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mediastinal (thymic) large B-cell lymphoma; Tissue or organ of origin: Lymph nodes of head, face and neck; Age at diagnosis: 51.2 years (18,691 days).
Specimen TCGA-GS-A9TZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6612a1be-f5c7-4d7a-9f0a-0c4b39aa38da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GS-A9TZ-10A (Blood Derived Normal), aliquot TCGA-GS-A9TZ-10A-01D-A38X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f01ae66-7b97-401d-bdff-74357bf6a7a0

The open-access MAF lists 453 somatic variants for this specimen: 331 protein-altering or splice-affecting, 117 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 286, Silent 117, Nonsense Mutation 23, Splice Site 7, Frame Shift Del 5, In Frame Del 3, Splice Region 3, Translation Start Site 2, Frame Shift Ins 2, Intron 2, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTB | c.258G>C p.W86C | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1554329554, COSV100079353; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.3215A>T p.D1072V | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101329918; called by muse, mutect2, varscan2
- ABHD17B | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 45/213 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.175); catalogued as COSV100330045; called by muse, mutect2, varscan2
- AC127029.3 | c.583C>T p.L195F | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100033172, COSV100033338; called by muse, mutect2, varscan2
- ACACB | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs978164597, COSV100622284; called by muse, mutect2, varscan2
- ACTB | c.38G>C p.G13A | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV59317380; called by muse, varscan2
- ACTG1 | c.123+1G>A p.X41_splice | Splice Site (SNP) | VAF 10/91 reads (11%) | catalogued as COSV100111837; called by muse, mutect2, varscan2
- ADAD2 | c.437C>T p.S146L (on ENST00000315906 / NM_001145400.2; = p.S218L on NM_139174.4) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.245); catalogued as rs774334290, COSV99235065; called by muse, mutect2, varscan2
- ADAMTS9 | c.2811G>A p.L937= | Splice Region (SNP) | VAF 10/66 reads (15%) | catalogued as rs373590492; called by muse, mutect2, varscan2
- ADARB2 | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV67221760, COSV67235082; called by muse, mutect2, varscan2
- ADGRB3 | c.3790G>A p.E1264K | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV99483479; called by muse, mutect2, varscan2
- AFF2 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 185/263 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV60680461; called by muse, mutect2, varscan2
- AHNAK | c.17564T>A p.L5855Q | Missense Mutation (SNP) | VAF 75/133 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as COSV99945485; called by muse, mutect2, varscan2
- AL645941.2 | c.95G>A p.S32N | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.22); catalogued as COSV101186808; called by muse, varscan2
- ALPG | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1366037743, COSV54966793; called by muse, mutect2, varscan2
- AP3M1 | c.304A>G p.I102V | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.116); catalogued as rs1487440243, COSV62332179; called by muse, mutect2, varscan2
- ARHGAP11A | c.2632G>A p.G878S | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs144493501; called by muse, mutect2, varscan2
- ARHGEF1 | c.2627G>A p.S876N | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100528850; called by muse, mutect2, varscan2
- ARID5B | c.172C>T p.Q58* | Nonsense Mutation (SNP) | VAF 17/112 reads (15%) | catalogued as COSV99688981; called by muse, mutect2, varscan2
- ASCC3 | c.5393C>T p.S1798F | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100976200; called by muse, mutect2, varscan2
- ASH2L | c.198C>G p.N66K | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV99166919; called by muse, varscan2
- ASPM | c.3233G>A p.S1078N | Missense Mutation (SNP) | VAF 147/554 reads (27%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV99659477; called by muse, mutect2, varscan2
- ATAD3A | c.359C>T p.T120I | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100186032; called by muse, mutect2, varscan2
- ATP10B | c.2527G>A p.V843I | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs1181042904, COSV100514092; called by mutect2, varscan2
- ATP10B | c.847G>A p.V283I | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as rs369830205, COSV100469038; called by muse, mutect2, varscan2
- ATP5ME | c.37C>T p.L13F | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.82); PolyPhen benign (0.006); catalogued as rs1486269726, COSV99726897; called by muse, mutect2, varscan2
- ATP6V0A1 | c.2390C>T p.S797L (on ENST00000343619 / NM_001378531.1; = p.S791L on NM_005177.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1429933097, COSV99230467; called by muse, mutect2, varscan2
- ATP6V0A4 | c.612G>A p.M204I | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100022625; called by muse, mutect2, varscan2
- ATPAF1 | c.613G>A p.E205K (on ENST00000574428; = p.E228K on NM_022745.4) | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as COSV100235974; called by muse, mutect2, varscan2
- ATR | c.118T>A p.F40I | Missense Mutation (SNP) | VAF 48/416 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.991); catalogued as COSV100637663; called by muse, varscan2
- ATRIP | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1265977995, COSV57177479; called by muse, mutect2, varscan2
- BACH2 | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1404131015, COSV99997987; called by muse, mutect2, varscan2
- BCL11B | c.1297G>A p.G433S (on ENST00000357195 / NM_001282237.2; = p.G362S on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100595123, COSV100595550; called by muse, mutect2, varscan2
- BCL2A1 | c.92G>A p.S31N | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs1443001456, COSV99144312; called by muse, mutect2, varscan2
- BCL9L | c.5G>A p.R2K | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as COSV100599516; called by muse, mutect2, varscan2
- BMP7 | c.1111A>G p.M371V | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV101215440; called by muse, mutect2, varscan2
- BMS1 | c.2611G>A p.D871N | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV100996450; called by muse, mutect2, varscan2
- BPIFB4 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs987026992, COSV100971418; called by muse, mutect2, varscan2
- BRCA1 | c.2017G>A p.E673K | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV100523273, COSV58792690; called by muse, mutect2, varscan2
- BRD2 | c.2342C>G p.S781* | Nonsense Mutation (SNP) | VAF 16/53 reads (30%) | catalogued as COSV100875550; called by muse, varscan2
- BRD4 | c.1705C>T p.P569S | Missense Mutation (SNP) | VAF 126/506 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.055); catalogued as rs201937726, COSV54595303; called by muse, mutect2, varscan2
- C12orf66 | c.1046T>A p.V349E | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100320542; called by muse, mutect2, varscan2
- C6orf62 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV100965852; called by muse, mutect2, varscan2
- CASD1 | c.1408C>T p.Q470* | Nonsense Mutation (SNP) | VAF 78/298 reads (26%) | catalogued as COSV99802247; called by muse, mutect2, varscan2
- CBARP | c.348C>A p.F116L (on ENST00000382477; = p.F122L on NM_152769.3) | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99289324; called by muse, mutect2, varscan2
- CCDC191 | c.1868A>G p.N623S | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as rs1183228031, COSV99877885; called by muse, mutect2, varscan2
- CCDC39 | c.2656T>C p.S886P | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.997); catalogued as COSV99867123; called by muse, mutect2, varscan2
- CCDC88B | c.4016G>A p.G1339E | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV100104993; called by muse, mutect2, varscan2
- CD58 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV101040998, COSV65648103; called by muse, mutect2, varscan2
- CD79A | c.73T>A p.Y25N | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV99701912; called by muse, mutect2, varscan2
- CD83 | c.126G>C p.Q42H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs199841901, COSV100997704, COSV64786786; called by muse, varscan2
- CDAN1 | c.2045G>A p.R682Q | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs201057681; called by muse, mutect2, varscan2
- CDK12 | c.1658C>T p.P553L | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT tolerated, low confidence (0.43); PolyPhen probably damaging (0.997); catalogued as rs1480899098, COSV101420361; called by muse, mutect2, varscan2
- CEMIP2 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.964); catalogued as rs200303233; called by muse, mutect2
- CFAP52 | c.872G>A p.G291D | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.485); catalogued as COSV100234767; called by muse, mutect2, varscan2
- CHD1 | c.3179G>A p.R1060K | Missense Mutation (SNP) | VAF 38/326 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.145); catalogued as COSV99399075; called by muse, varscan2
- CHD2 | c.4562C>G p.S1521* | Nonsense Mutation (SNP) | VAF 16/43 reads (37%) | catalogued as COSV101244681; called by muse, mutect2, varscan2
- CHRM3 | c.650C>A p.P217H | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV55087989, COSV99697444; called by muse, mutect2, varscan2
- CHST5 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100291735; called by muse, mutect2, varscan2
- CHST6 | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV100178233; called by muse, mutect2, varscan2
- CISH | c.229C>A p.L77I (on ENST00000348721 / NM_145071.4; = p.L94I on NM_013324.6) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1392329502, COSV100811711; called by muse, mutect2, varscan2
- CLEC1A | c.228C>G p.Y76* | Nonsense Mutation (SNP) | VAF 47/152 reads (31%) | catalogued as COSV100191121; called by muse, varscan2
- CMYA5 | c.4225G>T p.E1409* | Nonsense Mutation (SNP) | VAF 18/134 reads (13%) | catalogued as COSV101483818, COSV71407219; called by muse, mutect2, varscan2
- CNOT2 | c.431A>G p.Q144R | Missense Mutation (SNP) | VAF 62/155 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.747); catalogued as COSV99972334; called by muse, mutect2, varscan2
- CNRIP1 | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.176); catalogued as COSV99721106; called by muse, mutect2, varscan2
- CNTLN | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.005); catalogued as COSV99262724; called by muse, mutect2, varscan2
- CNTNAP4 | c.380A>C p.D127A | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as COSV100269291; called by muse, mutect2, varscan2
- CNTNAP5 | c.2737C>A p.Q913K | Missense Mutation (SNP) | VAF 46/216 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV101443027; called by muse, mutect2, varscan2
- COL1A1 | c.2663C>T p.P888L | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as CD040883, COSV99866345; called by muse, mutect2, varscan2
- COL23A1 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs755218615, COSV101178042; called by muse, mutect2, varscan2
- CPEB4 | c.557A>C p.D186A | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.449); catalogued as COSV99436663; called by muse, varscan2
- CRACDL | c.979G>A p.V327I | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0.01); catalogued as rs1165558900, COSV101193998; called by muse, mutect2, varscan2
- CRYBG1 | c.3433G>A p.E1145K | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765446944, COSV100954381; called by muse, mutect2, varscan2
- CSMD1 | c.6748A>G p.N2250D (on ENST00000520002; = p.N2249D on NM_033225.6) | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.987); catalogued as COSV100143442; called by muse, mutect2, varscan2
- CSNK1G3 | c.32C>G p.S11* | Nonsense Mutation (SNP) | VAF 29/176 reads (16%) | catalogued as COSV100631318; called by muse, mutect2, varscan2
- CSNK2A1 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV99424185; called by muse, mutect2, varscan2
- CSNK2A1 | c.127C>T p.R43* | Nonsense Mutation (SNP) | VAF 95/383 reads (25%) | catalogued as rs1301632648, COSV99424187; called by muse, mutect2, varscan2
- CTNND2 | c.1282G>A p.V428I | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs148824970; called by muse, mutect2, varscan2
- CYP27C1 | c.428A>T p.Y143F | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV100079654; called by muse, mutect2, varscan2
- CYP46A1 | c.904G>T p.A302S | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV99952429; called by muse, varscan2
- CYTH3 | c.505A>C p.M169L | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.622); catalogued as COSV100641256; called by muse, mutect2, varscan2
- DACT1 | c.2302G>T p.G768W | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100241573; called by muse, mutect2, varscan2
- DCST1 | c.635C>G p.T212S | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99792666; called by muse, mutect2, varscan2
- DDX3X | c.1805G>A p.R602Q (on ENST00000399959; = p.R603Q on NM_001356.5) | Missense Mutation (SNP) | VAF 77/118 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV101302338; called by muse, mutect2, varscan2
- DDX47 | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100774485; called by muse, mutect2, varscan2
- DNAH11 | c.8525G>A p.R2842Q | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs778407227, COSV60958515; called by muse, mutect2, varscan2
- DNAH2 | c.2332G>A p.E778K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as COSV101208989; called by muse, mutect2, varscan2
- DNAH9 | c.471G>A p.M157I | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV52335519; called by muse, mutect2, varscan2
- DNAH9 | c.5459A>C p.H1820P | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV99303955; called by muse, mutect2, varscan2
- DSEL | c.2684C>A p.T895K | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV100025237; called by muse, mutect2
- DTX3L | c.1321T>A p.F441I | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.357); catalogued as COSV99949855; called by muse, mutect2, varscan2
- DUSP13 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV100403262; called by muse, mutect2, varscan2
- DYNC1H1 | c.2405C>T p.S802F | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as COSV64135270; called by muse, mutect2, varscan2
- DYRK1B | c.1411+1G>A p.X471_splice | Splice Site (SNP) | VAF 20/69 reads (29%) | catalogued as COSV100546408; called by muse, mutect2, varscan2
- ECSCR | c.7A>C p.T3P | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); catalogued as COSV101579656; called by muse, mutect2, varscan2
- EIF1 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV60422620; called by muse, mutect2, varscan2
- ENOX1 | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as rs765142087, COSV54897670; called by muse, mutect2, varscan2
- EPHA4 | c.1252G>T p.G418* | Nonsense Mutation (SNP) | VAF 76/224 reads (34%) | catalogued as COSV99915510; called by muse, varscan2
- ERBB4 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs1297962291, COSV53500953; called by muse, mutect2, varscan2
- ERBIN | c.4166G>A p.G1389E (on ENST00000284037 / NM_001253697.2; = p.G1348E on NM_018695.4) | Missense Mutation (SNP) | VAF 157/363 reads (43%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.939); catalogued as COSV52329634; called by muse, mutect2, varscan2
- ESPL1 | c.5063C>T p.P1688L | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs1230823314, COSV99228882; called by muse, mutect2, varscan2
- EXOSC5 | c.469T>C p.C157R | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99652569; called by muse, varscan2
- FAM104A | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV52145050, COSV99277817; called by muse, mutect2, varscan2
- FAM50A | c.182A>G p.K61R | Missense Mutation (SNP) | VAF 64/91 reads (70%) | SIFT tolerated (0.05); PolyPhen benign (0.061); catalogued as COSV99340833; called by muse, mutect2, varscan2
- FASN | c.2388C>A p.F796L | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.973); catalogued as COSV100147287; called by muse, mutect2, varscan2
- FAT1 | c.11272G>A p.V3758M | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.284); catalogued as COSV101498977; called by muse, mutect2, varscan2
- FAT1 | c.5404G>C p.D1802H | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as COSV101498978, COSV101499455; called by muse, mutect2, varscan2
- FAT4 | c.3151C>T p.Q1051* | Nonsense Mutation (SNP) | VAF 23/143 reads (16%) | catalogued as COSV101271827; called by muse, mutect2, varscan2
- FBXL20 | c.29A>C p.K10T | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV99233717; called by muse, mutect2, varscan2
- FGF16 | c.377C>T p.S126L | Missense Mutation (SNP) | VAF 55/85 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs376876932, COSV101466310; called by muse, mutect2, varscan2
- FGFR2 | c.216G>C p.W72C | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100335329; called by muse, mutect2, varscan2
- FGFR4 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 71/148 reads (48%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV99448772; called by muse, mutect2, varscan2
- FKBP9 | c.1555G>A p.A519T | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as rs752543408, COSV54232267; called by muse, mutect2, varscan2
- FLT1 | c.3449T>G p.L1150R | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99147583, COSV99150899; called by muse, mutect2, varscan2
- FNDC7 | c.836C>T p.S279L | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.079); catalogued as COSV99600879; called by muse, mutect2, varscan2
- FRMPD4 | c.1541T>A p.L514Q | Missense Mutation (SNP) | VAF 45/64 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101042115; called by muse, mutect2, varscan2
- GASK1B | c.326T>C p.I109T | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99647261; called by muse, mutect2, varscan2
- GGPS1 | c.683C>G p.T228S | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.85); PolyPhen benign (0.035); catalogued as COSV51396864; called by muse, mutect2, varscan2
- GOPC | c.781G>T p.D261Y | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV99270673; called by muse, mutect2, varscan2
- H2AC15 | c.124G>T p.E42* | Nonsense Mutation (SNP) | VAF 35/110 reads (32%) | catalogued as COSV100356896, COSV57585526; called by muse, mutect2, varscan2
- HAO1 | c.118A>C p.N40H | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101113126; called by muse, mutect2, varscan2
- HCN1 | c.2366C>G p.S789W | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV100298492, COSV100299654, COSV57536392; called by muse, mutect2, varscan2
- HDAC9 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV101286164; called by muse, mutect2, varscan2
- HERC4 | c.2653G>C p.D885H (on ENST00000395198 / NM_022079.3; = p.D877H on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/176 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV99516513; called by muse, mutect2, varscan2
- HMCN1 | c.10879G>A p.E3627K | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.462); catalogued as COSV99623932; called by muse, mutect2, varscan2
- HOOK1 | c.1432C>T p.R478C | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.846); catalogued as rs906964084, COSV64618669; called by muse, mutect2, varscan2
- HOXD1 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1433714139, COSV100514088; called by muse, mutect2, varscan2
- HPSE2 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs778752620, COSV65189532; called by muse, mutect2, varscan2
- HS3ST5 | c.796C>A p.L266I | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.714); catalogued as COSV100450257; called by muse, mutect2, varscan2
- IGKV2-30 | c.280A>G p.T94A | Missense Mutation (SNP) | VAF 67/324 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as rs1422900477; called by muse, varscan2
- IGLL5 | c.299G>C p.G100A | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.972); catalogued as rs777202560, COSV66533697; called by muse, mutect2, varscan2
- INO80D | c.279G>T p.K93N | Missense Mutation (SNP) | VAF 56/174 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs747785950, COSV101305781; called by muse, mutect2, varscan2
- IQGAP3 | c.4101G>A p.L1367= | Splice Region (SNP) | VAF 23/82 reads (28%) | catalogued as COSV100752049; called by muse, mutect2, varscan2
- IRF8 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99236035; called by muse, varscan2
- ITGA10 | c.2612C>T p.S871F | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.595); catalogued as COSV100994692; called by muse, mutect2, varscan2
- ITGA2 | c.779+2T>A p.X260_splice | Splice Site (SNP) | VAF 18/149 reads (12%) | catalogued as COSV99670190; called by muse, mutect2, varscan2
- ITPKB | c.860G>A p.S287N | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs763066529, COSV55271172, COSV99683674; called by muse, mutect2, varscan2
- JAG2 | c.1352C>T p.P451L | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as rs1039776082, COSV100077889; called by muse, mutect2, varscan2
- KCNE5 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 34/47 reads (72%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.049); catalogued as rs1018945439, COSV100927692; called by muse, mutect2, varscan2
- KCNH5 | c.2072G>A p.R691Q | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.301); catalogued as rs200737420, COSV100525282; called by muse, mutect2, varscan2
- KCNJ8 | c.60G>C p.E20D | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99557356; called by muse, mutect2, varscan2
- KIF2B | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.107); catalogued as rs371085430, COSV52127441; called by muse, mutect2
- KLHL1 | c.305G>C p.R102T | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.026); catalogued as COSV100916991, COSV64780593; called by muse, mutect2, varscan2
- KRT23 | c.142A>G p.T48A | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV99266108; called by muse, mutect2, varscan2
- LINGO3 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV101347205; called by muse, mutect2, varscan2
- LOX | c.733C>G p.L245V | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV50242602, COSV99140590; called by muse, mutect2
- LRP1B | c.3725G>T p.G1242V | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101252217; called by muse, mutect2, varscan2
- LRP2 | c.3413C>T p.S1138F | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99786463, COSV99787991; called by muse, mutect2, varscan2
- LRRC30 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1245080637, COSV101274369, COSV101274411; called by muse, mutect2, varscan2
- LRRC39 | c.481G>T p.V161F | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.888); catalogued as COSV100734335; called by muse, mutect2, varscan2
- LRRN3 | c.767T>C p.L256P | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100067592; called by muse, mutect2, varscan2
- LRRTM1 | c.1036G>T p.E346* | Nonsense Mutation (SNP) | VAF 20/58 reads (34%) | catalogued as COSV99701753; called by muse, mutect2, varscan2
- LSM8 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.397); catalogued as rs1209028217, COSV50800702; called by muse, mutect2, varscan2
- LYST | c.3566C>G p.S1189C | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.497); catalogued as COSV101088115; called by muse, mutect2, varscan2
- MAP7D2 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT tolerated (0.29); PolyPhen benign (0.351); catalogued as COSV101107156; called by muse, mutect2, varscan2
- MAST4 | c.7496A>T p.N2499I (on ENST00000403625 / NM_001164664.2; = p.N2310I on NM_015183.3) | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as COSV99842759; called by muse, mutect2, varscan2
- MCF2L | c.997G>A p.E333K (on ENST00000375608; = p.E301K on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs754031767, COSV65049689, COSV65051818; called by muse, mutect2, varscan2
- MCM10 | c.815G>A p.R272Q (on ENST00000484800 / NM_182751.3; = p.R271Q on NM_018518.5) | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs556697001, COSV66333426, COSV66335100; called by muse, mutect2
- MEPCE | c.761C>T p.S254L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs760505363, COSV99439789; called by muse, mutect2, varscan2
- METTL1 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99141492; called by muse, mutect2, varscan2
- METTL4 | c.1085C>T p.S362L | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.342); catalogued as rs559475859, COSV99076961; called by muse, mutect2, varscan2
- MIA2 | c.2310C>A p.F770L | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV54490213, COSV99697265; called by muse, mutect2, varscan2
- MIB2 | c.2933G>A p.C978Y | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1234053266, COSV100598674, COSV61543296; called by muse, mutect2, varscan2
- MME | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.124); catalogued as COSV100852229; called by muse, mutect2, varscan2
- MMRN1 | c.3344G>T p.G1115V | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99306403; called by muse, mutect2, varscan2
- MPDZ | c.2753C>T p.S918L | Missense Mutation (SNP) | VAF 53/206 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs374745707, COSV59916252; called by muse, mutect2, varscan2
- MUC15 | c.797C>T p.T266M | Missense Mutation (SNP) | VAF 51/86 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as rs749905985, COSV55555517; called by muse, mutect2, varscan2
- MUC5B | c.12676G>A p.G4226S | Missense Mutation (SNP) | VAF 112/240 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs551298472, COSV71591689; called by muse, mutect2, varscan2
- MYBL1 | c.1832G>A p.S611N | Missense Mutation (SNP) | VAF 127/310 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV101576463; called by muse, mutect2, varscan2
- MYO9A | c.812T>G p.I271S | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV100612608; called by muse, mutect2, varscan2
- NAP1L5 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT tolerated (0.33); PolyPhen benign (0.235); catalogued as rs564016200, COSV99985273, COSV99985800; called by muse, mutect2, varscan2
- NCAM2 | c.976G>A p.G326R | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99521094; called by muse, mutect2, varscan2
- NCAPG | c.2884A>C p.T962P | Missense Mutation (SNP) | VAF 79/196 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99265631; called by muse, mutect2, varscan2
- NCKAP1 | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 23/293 reads (8%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.869); catalogued as COSV100719946; called by muse, mutect2
- NFATC2 | c.2423C>T p.S808L | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as rs779382116, COSV65352933; called by muse, mutect2, varscan2
- NFKBIA | c.79G>C p.D27H | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV99394900; called by muse, mutect2, varscan2
- NFKBIE | c.782+2T>C p.X261_splice (on ENST00000275015; = p.X122_splice on NM_004556.3) | Splice Site (SNP) | VAF 8/20 reads (40%) | catalogued as COSV99240864; called by muse, varscan2
- NFKBIE | c.751G>A p.A251T (on ENST00000275015; = p.A112T on NM_004556.3) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.112); catalogued as rs1389753887, COSV99240866; called by muse, varscan2
- NPEPPS | c.2749C>G p.P917A | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV100443399; called by muse, mutect2, varscan2
- NPR2 | c.249C>A p.S83R | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs1238734284, COSV100709286; called by muse, mutect2, varscan2
- NSDHL | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100938593; called by muse, mutect2, varscan2
- NUP188 | c.5225C>T p.A1742V | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.98); catalogued as rs1260351344, COSV100999323; called by muse, mutect2, varscan2
- OGFR | c.697G>A p.V233I | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as rs1167080670, COSV99283674; called by muse, mutect2, varscan2
- OPN1SW | c.602C>T p.T201M | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as rs1041014166, COSV99975440; called by muse, mutect2, varscan2
- OR13C9 | c.307C>T p.L103F | Missense Mutation (SNP) | VAF 160/344 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs766134031, COSV99403339; called by muse, mutect2, varscan2
- OR2AK2 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs773845973, COSV63552754, COSV63560644; called by muse, mutect2, varscan2
- OR5M1 | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 97/166 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as COSV101591530; called by muse, mutect2, varscan2
- OR5M8 | c.750C>A p.F250L | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100510535; called by muse, mutect2, varscan2
- OR6B3 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as rs371957226; called by muse, mutect2, varscan2
- OR6S1 | c.460G>A p.G154R | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1566581587, COSV100289262; called by muse, mutect2, varscan2
- OSTM1 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99513951; called by muse, mutect2, varscan2
- OXCT1 | c.40T>C p.C14R | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs774315290, COSV99541686; called by muse, mutect2, varscan2
- PALB2 | c.3433G>A p.G1145S | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs180177137, COSV99848018; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PARD3 | c.2000C>G p.S667C | Missense Mutation (SNP) | VAF 66/274 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs142553947, COSV100400182; called by muse, mutect2, varscan2
- PARD3B | c.1817C>T p.S606F | Missense Mutation (SNP) | VAF 58/286 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV100592107; called by muse, mutect2, varscan2
- PCDH15 | c.2483T>C p.V828A | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100214975; called by muse, mutect2, varscan2
- PCDH15 | c.1566G>A p.M522I | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.241); catalogued as rs1159351115, COSV57268433; called by muse, mutect2, varscan2
- PCDHA5 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.143); catalogued as COSV100972086; called by muse, mutect2, varscan2
- PCED1A | c.1269dup p.P424Afs*57 | Frame Shift Ins (INS) | VAF 26/82 reads (32%) | catalogued as rs772305388; called by mutect2, varscan2
- PDE1A | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.297); catalogued as rs766619813, COSV100112887; called by muse, mutect2, varscan2
- PGAP6 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as COSV99170573; called by muse, varscan2
- PGK2 | c.801A>C p.K267N | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV100505321; called by muse, mutect2, varscan2
- PHC1 | c.2405A>C p.Y802S | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV99134080; called by muse, mutect2, varscan2
- PHLPP2 | c.3329T>A p.L1110* | Nonsense Mutation (SNP) | VAF 15/62 reads (24%) | catalogued as COSV100673485; called by muse, mutect2, varscan2
- PHOX2B | c.890C>T p.S297L | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV56928721; called by muse, mutect2, varscan2
- PIM2 | c.93G>C p.E31D | Missense Mutation (SNP) | VAF 80/103 reads (78%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as COSV99331571; called by muse, mutect2, varscan2
- PKHD1L1 | c.12341T>C p.V4114A | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.942); catalogued as rs1483303527, COSV101005315; called by muse, mutect2, varscan2
- PLCE1 | c.3688C>T p.R1230C | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1338175454, COSV99593442; called by muse, mutect2, varscan2
- PLCL1 | c.2402A>T p.D801V | Missense Mutation (SNP) | VAF 73/289 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101406786; called by muse, mutect2, varscan2
- PLEKHS1 | c.638G>A p.R213Q (on ENST00000369310 / NM_182601.1; = p.R219Q on NM_024889.5) | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.372); catalogued as rs267602368, COSV63054937; called by muse, mutect2, varscan2
- PLPPR4 | c.538G>T p.G180C | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100926691; called by muse, mutect2, varscan2
- POLR2B | c.1004G>T p.R335I | Missense Mutation (SNP) | VAF 154/319 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1203059950, COSV58898525; called by muse, mutect2, varscan2
- POPDC3 | c.594G>A p.Q198= | Splice Region (SNP) | VAF 41/155 reads (26%) | catalogued as rs1199410191, COSV99633347; called by muse, mutect2, varscan2
- PPID | c.646G>A p.V216I | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as rs555544713, COSV100306703; called by muse, mutect2, varscan2
- PPP1CA | c.254G>C p.S85T | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); catalogued as COSV100334831; called by muse, mutect2, varscan2
- PPP1R27 | c.422A>G p.Y141C | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1344533143, COSV100367327; called by muse, mutect2, varscan2
- PPP1R36 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV53904334; called by muse, varscan2
- PRDM16 | c.1023C>G p.N341K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV99575419; called by muse, mutect2, varscan2
- PRDM2 | c.1705T>C p.Y569H | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs750390685, COSV99340760; called by muse, mutect2, varscan2
- PRDM8 | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs1323000516, COSV100324915; called by muse, mutect2, varscan2
- PRRC2A | c.4841T>G p.L1614* | Nonsense Mutation (SNP) | VAF 26/62 reads (42%) | catalogued as COSV99276418; called by muse, mutect2, varscan2
- PRRC2B | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as COSV100621395; called by muse, mutect2, varscan2
- PSEN1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 30/77 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV56194763; called by muse, mutect2, varscan2
- PSKH2 | c.432G>T p.E144D | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV99404957; called by muse, mutect2, varscan2
- PTGS2 | c.158A>T p.N53I | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100821666; called by muse, mutect2, varscan2
- PTH | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 78/156 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as CM126946, COSV56378363; called by muse, mutect2, varscan2
- PTPN2 | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs867096066, COSV100518326; called by muse, mutect2, varscan2
- PTPRB | c.5278G>A p.A1760T | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99715681; called by muse, mutect2, varscan2
- PTPRD | c.1805C>T p.A602V | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV61936876, COSV61956639; called by muse, mutect2
- PXDN | c.2598C>A p.D866E | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV99412246; called by muse, mutect2, varscan2
- RASIP1 | c.2782G>T p.D928Y | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.941); catalogued as COSV99710464; called by muse, mutect2, varscan2
- REV3L | c.7680+1G>A p.X2560_splice | Splice Site (SNP) | VAF 19/79 reads (24%) | catalogued as COSV100724843; called by muse, mutect2, varscan2
- RIN2 | c.2394G>T p.K798N (on ENST00000255006 / NM_001242581.1; = p.K749N on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54787793; called by muse, mutect2, varscan2
- RPS6KA5 | c.1189C>T p.H397Y | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV100002061; called by muse, mutect2, varscan2
- SCN9A | c.1221A>C p.E407D | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV57598828; called by muse, mutect2, varscan2
- SEMA7A | c.728T>A p.F243Y | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763297947, COSV99984540; called by muse, mutect2, varscan2
- SETD1A | c.1571G>C p.R524T | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.039); catalogued as COSV99352384; called by muse, mutect2, varscan2
- SGIP1 | c.473G>C p.R158T | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV99390422; called by muse, mutect2, varscan2
- SH3RF2 | c.1247G>C p.G416A | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.268); catalogued as COSV100767589; called by muse, mutect2, varscan2
- SHLD2 | c.2058T>G p.S686R | Missense Mutation (SNP) | VAF 104/369 reads (28%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.525); catalogued as COSV100078833; called by muse, mutect2, varscan2
- SHMT1 | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100363454; called by muse, mutect2, varscan2
- SI | c.3766C>A p.Q1256K | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100013884, COSV100015767, COSV52264857; called by muse, mutect2, varscan2
- SLC22A9 | c.70C>A p.L24I | Missense Mutation (SNP) | VAF 106/209 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV54165925; called by muse, mutect2, varscan2
- SLC25A13 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 15/51 reads (29%) | catalogued as COSV99673032; called by muse, mutect2, varscan2
- SLC30A4 | c.391G>C p.G131R | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99970111; called by muse, varscan2
- SLC37A3 | c.1078C>T p.L360F | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV100405271; called by muse, mutect2, varscan2
- SLC6A15 | c.1356T>A p.H452Q | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.972); catalogued as COSV99880142; called by muse, mutect2, varscan2
- SMARCA4 | c.2896C>T p.R966W | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1227826852, COSV60788496; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMC1B | c.1472C>T p.T491I | Missense Mutation (SNP) | VAF 73/259 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as COSV100662933; called by muse, mutect2, varscan2
- SOCS1 | c.569A>G p.N190S | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.069); catalogued as COSV100130159; called by muse, varscan2
- SOCS1 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.58); PolyPhen benign (0.029); catalogued as COSV100130182; called by muse, varscan2
- SON | c.3145A>C p.M1049L | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV99276772; called by muse, mutect2, varscan2
- SRP72 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100714241; called by muse, mutect2, varscan2
- ST7L | c.816G>T p.Q272H | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.125); catalogued as COSV100573633; called by muse, mutect2, varscan2
- STAT1 | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs865962653, COSV100738429; called by muse, mutect2, varscan2
- STAT6 | c.1928C>T p.P643L | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV100272497; called by muse, mutect2, varscan2
- STAT6 | c.1259A>G p.N420S | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV104411270, COSV55669486; called by muse, mutect2, varscan2
- STRIP2 | c.1684G>A p.D562N | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759758349, COSV50804585, COSV99973446; called by muse, mutect2, varscan2
- STXBP3 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.939); catalogued as COSV99600882; called by muse, mutect2, varscan2
- SVIL | c.6367G>C p.E2123Q (on ENST00000355867 / NM_021738.3; = p.E1697Q on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV100880890; called by muse, mutect2, varscan2
- SYNPO2 | c.3692C>T p.A1231V | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100204827; called by muse, mutect2, varscan2
- TAC3 | c.127C>T p.L43F | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.233); catalogued as COSV100269801; called by muse, mutect2, varscan2
- TACC2 | c.8755G>A p.A2919T (on ENST00000334433; = p.A997T on NM_006997.4) | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757107024, COSV99586566; called by muse, mutect2, varscan2
- TBC1D10C | c.952A>G p.I318V | Missense Mutation (SNP) | VAF 62/139 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.028); catalogued as COSV100408107; called by muse, mutect2, varscan2
- TBC1D9 | c.2350A>C p.I784L | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV101464259; called by muse, mutect2, varscan2
- TENM4 | c.2123C>T p.P708L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.011); catalogued as rs924989886, COSV53611890; called by muse, mutect2, varscan2
- TGFBR3 | c.2336T>A p.F779Y | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.258); catalogued as COSV99282378; called by muse, mutect2, varscan2
- TGIF2 | c.193-1G>T p.X65_splice | Splice Site (SNP) | VAF 16/74 reads (22%) | catalogued as COSV65836286; called by muse, varscan2
- TLN2 | c.1518G>A p.M506I | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.76); PolyPhen benign (0.029); catalogued as COSV100167947; called by muse, mutect2, varscan2
- TLR4 | c.1828G>T p.A610S (on ENST00000355622 / NM_138554.5; = p.A570S on NM_003266.4) | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as COSV100842646; called by muse, mutect2, varscan2
- TMEM135 | c.271A>T p.K91* | Nonsense Mutation (SNP) | VAF 101/212 reads (48%) | catalogued as COSV100449324; called by muse, mutect2, varscan2
- TMEM30A | c.575C>G p.S192C | Missense Mutation (SNP) | VAF 56/251 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV100034698; called by muse, mutect2, varscan2
- TNFAIP3 | c.1737C>A p.C579* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as COSV99396319; called by muse, mutect2, varscan2
- TNFAIP3 | c.2312G>A p.G771D | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99396321; called by muse, mutect2, varscan2
- TPO | c.406T>C p.Y136H | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV100219636; called by muse, mutect2, varscan2
- TRANK1 | c.4246A>T p.M1416L | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.325); catalogued as COSV100081387; called by muse, mutect2, varscan2
- TRIM46 | c.1895C>T p.P632L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.647); catalogued as rs767343114, COSV100103843; called by mutect2, varscan2
- TRIO | c.4388G>A p.R1463Q | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs373502206; called by muse, mutect2
- TSC22D2 | c.1357C>T p.Q453* | Nonsense Mutation (SNP) | VAF 4/47 reads (9%) | catalogued as COSV100721181; called by muse, mutect2
- TSPAN31 | c.176T>C p.I59T | Missense Mutation (SNP) | VAF 77/154 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1174303149, COSV99222176; called by muse, mutect2, varscan2
- TTC21B | c.2149G>A p.E717K | Missense Mutation (SNP) | VAF 50/278 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.437); catalogued as COSV54637252; called by muse, mutect2, varscan2
- UACA | c.1979C>T p.S660L | Missense Mutation (SNP) | VAF 91/337 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100537231; called by muse, mutect2, varscan2
- UHRF1 | c.268C>G p.L90V (on ENST00000612630 / NM_001290050.1; = p.L103V on NM_013282.4) | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as COSV99503292; called by muse, mutect2, varscan2
- UNC13C | c.6064G>A p.D2022N | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs748619710, COSV99511459; called by muse, mutect2, varscan2
- UNC5C | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101497779; called by muse, mutect2, varscan2
- UPF1 | c.1220G>A p.R407Q (on ENST00000599848 / NM_001297549.2; = p.R396Q on NM_002911.4) | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV53195590, COSV99438772; called by muse, mutect2, varscan2
- VCPIP1 | c.1867T>A p.Y623N | Missense Mutation (SNP) | VAF 75/176 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100125322; called by muse, mutect2, varscan2
- VCPIP1 | c.1663A>G p.I555V | Missense Mutation (SNP) | VAF 74/155 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1225630121, COSV100125325; called by muse, mutect2, varscan2
- VCPKMT | c.98A>G p.Y33C | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1327529889, COSV53569734; called by muse, mutect2, varscan2
- VN1R1 | c.455C>A p.P152H | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100320576; called by muse, mutect2, varscan2
- WDR24 | c.2249C>G p.S750* (on ENST00000248142; = p.S620* on NM_032259.4) | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as COSV99555360; called by muse, mutect2, varscan2
- WDR72 | c.2879A>T p.N960I | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV100854183; called by muse, mutect2, varscan2
- XIRP2 | c.8039A>G p.Q2680R (on ENST00000628543; = p.Q2855R on NM_152381.6) | Missense Mutation (SNP) | VAF 104/320 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as COSV54710042, COSV99738279; called by muse, varscan2
- XPO6 | c.292C>T p.H98Y | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV100484659; called by muse, mutect2
- XPO7 | c.2353C>T p.R785* | Nonsense Mutation (SNP) | VAF 23/71 reads (32%) | catalogued as COSV53020249; called by muse, mutect2, varscan2
- YY1AP1 | c.620G>A p.G207E (on ENST00000295566 / NM_139118.2; = p.G130E on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/254 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.914); catalogued as COSV99803411; called by muse, mutect2, varscan2
- ZC3HAV1 | c.124C>T p.Q42* | Nonsense Mutation (SNP) | VAF 12/84 reads (14%) | catalogued as COSV99648205; called by muse, mutect2, varscan2
- ZDHHC17 | c.1741T>G p.S581A | Missense Mutation (SNP) | VAF 34/298 reads (11%) | SIFT tolerated (0.87); PolyPhen benign (0.314); catalogued as COSV100601990; called by muse, mutect2, varscan2
- ZFHX4 | c.364A>T p.S122C | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99255811; called by muse, mutect2, varscan2
- ZIM3 | c.1043C>G p.S348C | Missense Mutation (SNP) | VAF 78/277 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99517619; called by muse, mutect2, varscan2
- ZNF208 | c.1963C>A p.H655N | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101236793; called by muse, mutect2, varscan2
- ZNF234 | c.1154C>T p.S385L | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101468333; called by muse, mutect2, varscan2
- ZNF256 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 44/192 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV99990597; called by muse, mutect2, varscan2
- ZNF274 | c.659G>A p.W220* (on ENST00000610905; = p.W115* on NM_016324.3) | Nonsense Mutation (SNP) | VAF 13/51 reads (25%) | catalogued as COSV100464687; called by muse, mutect2, varscan2
- ZNF347 | c.2162G>A p.R721H | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs150489253, COSV100498380; called by muse, mutect2, varscan2
- ZNF425 | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs751063490, COSV100955382; called by muse, mutect2, varscan2
- ZNF454 | c.206G>A p.R69K | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs760585050, COSV100194536; called by muse, mutect2, varscan2
- ZNF512B | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs371234637; called by muse, mutect2, varscan2
- ZNF615 | c.652C>G p.Q218E | Missense Mutation (SNP) | VAF 64/242 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as COSV100943711; called by muse, mutect2, varscan2
- ZNF616 | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as COSV100348074; called by muse, mutect2, varscan2
- ZNF649 | c.794G>C p.S265T | Missense Mutation (SNP) | VAF 70/256 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs762276255, COSV100030730; called by muse, mutect2, varscan2
- ZNF708 | c.291A>C p.Q97H | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV100803035; called by muse, mutect2, varscan2
- ZNF836 | c.1616C>T p.S539L | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV100440593; called by muse, mutect2, varscan2
- ABCA2 | c.3784dup p.Q1262Pfs*102 (on ENST00000614293; = p.Q1232Pfs*102 on NM_001606.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 8/42 reads (19%) | called by mutect2, pindel, varscan2
- CA3 | c.221dup p.Y74* | Nonsense Mutation (INS) | VAF 20/54 reads (37%) | called by mutect2, pindel, varscan2
- COL22A1 | c.2086-2_2086-1del p.X696_splice | Splice Site (DEL) | VAF 9/92 reads (10%) | called by mutect2, pindel, varscan2
- ERCC6L2 | c.3609G>C p.K1203N | Missense Mutation (SNP) | VAF 39/254 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IGHE | c.1201G>C p.D401H | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- IGHE | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.029); called by muse, varscan2
- IGLC3 | c.127A>G p.K43E | Missense Mutation (SNP) | VAF 56/134 reads (42%) | PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- IGLJ3 | c.121T>A p.F41I | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- KLRK1 | c.91del p.S31Qfs*11 | Frame Shift Del (DEL) | VAF 55/262 reads (21%) | called by mutect2, pindel, varscan2
- MYL6 | c.407del p.N136Mfs*10 | Frame Shift Del (DEL) | VAF 11/72 reads (15%) | called by mutect2, pindel, varscan2
- PRAMEF10 | c.455A>G p.D152G | Missense Mutation (SNP) | VAF 29/259 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- PSMG2 | c.438del p.M147Cfs*9 | Frame Shift Del (DEL) | VAF 15/143 reads (10%) | called by mutect2, pindel, varscan2
- RALGDS | c.2042_2057del p.S681Tfs*134 | Frame Shift Del (DEL) | VAF 8/67 reads (12%) | called by mutect2, pindel
- RLF | c.1022_1024del p.R341del | In Frame Del (DEL) | VAF 42/161 reads (26%) | called by pindel, varscan2
- SOCS1 | c.233_234del p.G78Vfs*38 | Frame Shift Del (DEL) | VAF 9/20 reads (45%) | called by pindel, varscan2
- SRPRB | c.46G>C p.G16R | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- THOC5 | c.424_426del p.K142del | In Frame Del (DEL) | VAF 13/55 reads (24%) | called by mutect2, pindel, varscan2
- UACA | c.3097_3102del p.L1033_K1034del | In Frame Del (DEL) | VAF 46/211 reads (22%) | called by mutect2, pindel, varscan2
- ACADSB | c.1017G>A p.V339= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV100715070; called by muse, mutect2, varscan2
- ACTB | c.414T>A p.A138= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV100079349; called by muse, mutect2, varscan2
- AL031777.2 | c.279G>A p.E93= | Silent (SNP) | VAF 49/180 reads (27%) | catalogued as COSV61911739, COSV61912554; called by muse, varscan2
- ATP12A | c.3081C>T p.L1027= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as rs753934399, COSV99516980; called by muse, mutect2, varscan2
- BACH2 | c.27C>T p.S9= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV99997988; called by muse, mutect2, varscan2
- BRCA2 | c.1074G>A p.V358= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as rs276174805, COSV101203894; ClinVar: likely benign; called by muse, mutect2
- BTBD17 | c.834C>T p.H278= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs1268269009, COSV64729905; called by muse, mutect2, varscan2
- C1QTNF1 | c.525C>T p.Y175= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as rs566729160, COSV59263273; called by muse, mutect2, varscan2
- C9orf24 | c.771A>T p.L257= | Silent (SNP) | VAF 28/121 reads (23%) | catalogued as COSV99897716; called by muse, mutect2, varscan2
- CARNMT1 | c.369A>G p.L123= | Silent (SNP) | VAF 44/149 reads (30%) | catalogued as rs541125527, COSV100961058; called by muse, mutect2, varscan2
- CCNH | c.36C>T p.T12= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as rs746608462, COSV99907133; called by muse, mutect2, varscan2
- CDK11B | c.150G>A p.E50= | Silent (SNP) | VAF 13/134 reads (10%) | catalogued as COSV100477237; called by muse, mutect2, varscan2
- CEP83 | c.2073A>G p.K691= | Silent (SNP) | VAF 44/341 reads (13%) | catalogued as COSV51577596; called by muse, varscan2
- CLEC1A | c.717C>T p.I239= | Silent (SNP) | VAF 7/111 reads (6%) | catalogued as rs1297028522, COSV59531868; called by muse, mutect2
- CNTN5 | c.2934T>A p.P978= | Silent (SNP) | VAF 12/130 reads (9%) | catalogued as COSV99672707; called by muse, mutect2
- CORO1A | c.1176C>G p.L392= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as COSV99531804; called by muse, mutect2, varscan2
- CPEB4 | c.501T>C p.G167= | Silent (SNP) | VAF 34/146 reads (23%) | catalogued as COSV99436660; called by muse, varscan2
- CPNE8 | c.1587T>G p.A529= | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as COSV100503860; called by mutect2, varscan2
- CUBN | c.6477T>C p.P2159= | Silent (SNP) | VAF 25/184 reads (14%) | catalogued as rs1390348716, COSV64721269; called by muse, mutect2, varscan2
- DDX47 | c.63G>A p.E21= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV100774484; called by muse, mutect2, varscan2
- DOCK10 | c.6183G>A p.L2061= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as COSV99287544; called by muse, mutect2, varscan2
- DOCK6 | c.4284G>A p.Q1428= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV99624651; called by muse, mutect2, varscan2
- DTL | c.231A>C p.R77= | Silent (SNP) | VAF 62/528 reads (12%) | catalogued as COSV100877137; called by muse, varscan2
- DVL1 | c.1371C>T p.H457= (on ENST00000378888 / NM_001330311.2; = p.H432= on NM_004421.3) | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as rs151161721; called by muse, mutect2, varscan2
- EBNA1BP2 | c.300C>T p.D100= | Silent (SNP) | VAF 34/117 reads (29%) | catalogued as rs367548162; called by muse, mutect2, varscan2
- EEF2KMT | c.300G>A p.L100= | Silent (SNP) | VAF 50/146 reads (34%) | catalogued as COSV101435294; called by muse, mutect2, varscan2
- EGR2 | c.75C>T p.I25= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV99653973; called by muse, varscan2
- EIF3F | c.981C>G p.L327= | Silent (SNP) | VAF 42/76 reads (55%) | catalogued as COSV100562472; called by muse, mutect2, varscan2
- EP400 | c.3807G>A p.L1269= | Silent (SNP) | VAF 34/81 reads (42%) | catalogued as COSV100200375; called by muse, mutect2, varscan2
- EPPK1 | c.4431C>T p.Y1477= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as rs781958862, COSV101599731; called by muse, mutect2, varscan2
- FREM1 | c.5472C>A p.V1824= | Silent (SNP) | VAF 17/278 reads (6%) | catalogued as COSV66519354; called by muse, mutect2
- FREM2 | c.9336C>T p.V3112= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV99746718; called by muse, mutect2, varscan2
- FSIP2 | c.16872C>T p.D5624= | Silent (SNP) | VAF 73/188 reads (39%) | catalogued as COSV100553938; called by muse, mutect2, varscan2
- FSIP2 | c.17472C>G p.L5824= | Silent (SNP) | VAF 56/192 reads (29%) | catalogued as COSV100553941; called by muse, mutect2, varscan2
- FZD7 | c.372C>T p.C124= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as rs1230100560, COSV99636805; called by muse, mutect2, varscan2
- GALNT11 | c.1773C>T p.V591= | Silent (SNP) | VAF 48/162 reads (30%) | catalogued as rs368113531; called by muse, mutect2, varscan2
- GEMIN2 | c.435G>A p.K145= | Silent (SNP) | VAF 27/107 reads (25%) | catalogued as COSV99158037, COSV99158472; called by muse, mutect2, varscan2
- GRIN2A | c.612C>T p.I204= | Silent (SNP) | VAF 6/65 reads (9%) | catalogued as COSV100408222; called by muse, varscan2
- H1-4 | c.282G>A p.V94= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as rs549787183, COSV99175207; called by muse, mutect2, varscan2
- H2BC11 | c.93G>A p.K31= | Silent (SNP) | VAF 13/123 reads (11%) | catalogued as COSV100345591; called by muse, mutect2, varscan2
- HCN2 | c.1332C>T p.T444= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs755029604, COSV99241224; called by muse, mutect2, varscan2
- HGS | c.1674G>A p.A558= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs190451033; called by muse, mutect2, varscan2
- HHIPL2 | c.135C>T p.C45= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV100596564; called by muse, mutect2, varscan2
- HSPG2 | c.5340C>T p.S1780= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs777957604, COSV101020393; called by muse, mutect2, varscan2
- IFI27L2 | c.231C>T p.I77= | Silent (SNP) | VAF 15/105 reads (14%) | catalogued as COSV99462949; called by muse, mutect2, varscan2
- INPPL1 | c.3624C>T p.I1208= | Silent (SNP) | VAF 44/81 reads (54%) | catalogued as rs776975989, COSV99995806, COSV99996054; called by muse, mutect2, varscan2
- IQGAP1 | c.426A>G p.R142= | Silent (SNP) | VAF 46/167 reads (28%) | catalogued as COSV99184860; called by muse, mutect2, varscan2
- IRF2BP2 | c.1248A>G p.E416= | Silent (SNP) | VAF 34/139 reads (24%) | catalogued as COSV100784243; called by muse, mutect2, varscan2
- IRF8 | c.354A>G p.Q118= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as COSV99236038; called by muse, varscan2
- ITPRID1 | c.480C>T p.I160= | Silent (SNP) | VAF 37/112 reads (33%) | catalogued as COSV100085617; called by muse, mutect2, varscan2
- KCNAB3 | c.132G>A p.P44= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as rs1033543877, COSV100366392, COSV58050218; called by muse, mutect2, varscan2
- LAMA2 | c.1902C>T p.I634= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV101369980; called by muse, mutect2
- LEMD3 | c.969G>T p.A323= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as COSV100384176; called by muse, mutect2, varscan2
- LRRN3 | c.1296A>G p.L432= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV100067595; called by muse, mutect2, varscan2
- LRRTM1 | c.1035G>T p.P345= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV54445577, COSV99701757; called by muse, mutect2, varscan2
- LRWD1 | c.1836C>A p.G612= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV99484444; called by muse, mutect2, varscan2
- LY9 | c.624C>T p.T208= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs755111415, COSV54434577; called by muse, mutect2, varscan2
- MAGI2 | c.1884G>A p.V628= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as COSV100832693; called by muse, mutect2, varscan2
- MESD | c.474C>T p.I158= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs372944817, COSV99930726; called by muse, mutect2, varscan2
- MTMR14 | c.219G>C p.V73= | Silent (SNP) | VAF 20/121 reads (17%) | catalogued as rs913801054, COSV99931119; called by muse, mutect2, varscan2
- MUC5B | c.14733C>T p.S4911= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as rs938380802, COSV101500026; called by muse, mutect2, varscan2
- NACA | c.54G>A p.Q18= | Silent (SNP) | VAF 29/63 reads (46%) | catalogued as rs1437519178, COSV100771062; called by muse, mutect2, varscan2
- NALCN | c.1014G>A p.S338= | Silent (SNP) | VAF 50/165 reads (30%) | catalogued as rs141596606; called by muse, mutect2, varscan2
- NCKAP1 | c.516C>T p.D172= | Silent (SNP) | VAF 50/232 reads (22%) | catalogued as COSV100719950; called by muse, mutect2, varscan2
- NCR1 | c.729G>A p.Q243= | Silent (SNP) | VAF 30/77 reads (39%) | catalogued as COSV99400746; called by muse, mutect2, varscan2
- NTHL1 | c.537C>T p.V179= (on ENST00000219066; = p.V171= on NM_002528.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs140211154; ClinVar: likely benign; called by muse, mutect2
- OPRK1 | c.531C>T p.I177= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as COSV55569241; called by muse, mutect2, varscan2
- OR2M2 | c.459T>C p.S153= | Silent (SNP) | VAF 70/249 reads (28%) | catalogued as COSV100677159; called by muse, mutect2, varscan2
- OXR1 | c.363C>T p.N121= (on ENST00000442977 / NM_001198532.1; = p.N120= on NM_018002.3) | Silent (SNP) | VAF 38/174 reads (22%) | catalogued as rs537961089, COSV100366702; called by muse, mutect2, varscan2
- PAK4 | c.99G>A p.T33= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as rs757615009, COSV58945802; called by muse, mutect2, varscan2
- PCDHA4 | c.144C>T p.I48= | Silent (SNP) | VAF 37/109 reads (34%) | catalogued as COSV100793137; called by muse, mutect2, varscan2
- PDHA1 | c.375C>T p.F125= | Silent (SNP) | VAF 171/256 reads (67%) | catalogued as COSV63328438; called by muse, mutect2, varscan2
- PHF19 | c.415C>T p.L139= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV100384261; called by muse, mutect2, varscan2
- PKD1 | c.3819C>T p.T1273= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs764979703, COSV99237115, COSV99238722; called by muse, mutect2, varscan2
- PLCL1 | c.372C>T p.V124= | Silent (SNP) | VAF 39/118 reads (33%) | catalogued as COSV101406785; called by muse, varscan2
- PLEKHA7 | c.39G>A p.E13= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as rs777764634, COSV100850069; called by muse, mutect2, varscan2
- PLXNA2 | c.3885G>A p.E1295= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV65438077; called by muse, mutect2, varscan2
- PNPLA5 | c.72C>T p.H24= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as rs748898005, COSV99336465; called by muse, mutect2, varscan2
- PTPN9 | c.1374C>A p.R458= | Silent (SNP) | VAF 24/94 reads (26%) | catalogued as COSV100144004; called by muse, mutect2, varscan2
- PTPRF | c.5697C>T p.L1899= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs765441872, COSV63442104; called by muse, mutect2, varscan2
- PTPRO | c.2013T>C p.V671= | Silent (SNP) | VAF 30/78 reads (38%) | catalogued as COSV99839635; called by muse, mutect2, varscan2
- PXDN | c.2325C>T p.F775= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as COSV99412249; called by muse, mutect2, varscan2
- RAB22A | c.435A>G p.V145= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as rs759870210, COSV99719963; called by muse, mutect2, varscan2
- RHBDD3 | c.252G>A p.L84= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as COSV99328408; called by muse, mutect2, varscan2
- RPUSD3 | c.183C>A p.P61= | Silent (SNP) | VAF 27/105 reads (26%) | catalogued as COSV101094616; called by muse, mutect2, varscan2
- RUSF1 | c.1335C>T p.T445= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as rs780387504, COSV57890879; called by muse, mutect2, varscan2
- SEC23B | c.261C>T p.F87= | Silent (SNP) | VAF 77/652 reads (12%) | catalogued as rs1568596980, COSV99357380; called by muse, mutect2, varscan2
- SH2B2 | c.1008G>A p.Q336= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV100159220; called by muse, mutect2, varscan2
- SIAH2 | c.48C>T p.S16= | Silent (SNP) | VAF 27/79 reads (34%) | catalogued as rs920240337, COSV100469088; called by muse, mutect2, varscan2
- SLC16A13 | c.669C>T p.L223= | Silent (SNP) | VAF 39/92 reads (42%) | catalogued as COSV100338553; called by muse, mutect2, varscan2
- SLC26A4 | c.1212C>A p.T404= | Silent (SNP) | VAF 22/240 reads (9%) | catalogued as COSV99706529; called by muse, mutect2
- SLC30A4 | c.60G>A p.P20= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as rs1247588187, COSV99970117; called by muse, mutect2, varscan2
- SOCS1 | c.529C>T p.L177= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV100130161, COSV59658959, COSV59659750; called by muse, varscan2
- SOCS1 | c.162C>T p.H54= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV100130180; called by muse, varscan2
- SORCS1 | c.2499C>T p.I833= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV99543137; called by muse, mutect2, varscan2
- SPRY2 | c.600C>A p.I200= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV101001657; called by muse, mutect2, varscan2
- ST6GAL2 | c.300C>A p.A100= | Silent (SNP) | VAF 65/173 reads (38%) | catalogued as COSV100867646; called by muse, mutect2, varscan2
- STX16 | c.15T>C p.R5= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV100397205; called by muse, mutect2, varscan2
- TAPT1 | c.1452G>A p.Q484= | Silent (SNP) | VAF 60/137 reads (44%) | catalogued as COSV100460955; called by muse, mutect2, varscan2
- TBCC | c.360G>A p.L120= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs751850422, COSV99773925; called by muse, mutect2, varscan2
- TENT2 | c.27C>A p.R9= | Silent (SNP) | VAF 163/398 reads (41%) | catalogued as COSV57136278, COSV99706266; called by muse, mutect2, varscan2
- TRHDE | c.2727G>A p.L909= | Silent (SNP) | VAF 58/128 reads (45%) | catalogued as COSV99669036; called by muse, mutect2, varscan2
- TTC6 | c.1215C>T p.F405= (on ENST00000267368; = p.F1771= on NM_001310135.3) | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as rs1187897269, COSV99941525; called by muse, mutect2, varscan2
- TYRP1 | c.948T>A p.A316= | Silent (SNP) | VAF 37/193 reads (19%) | catalogued as rs754642924, COSV101141154; called by muse, mutect2, varscan2
- UBE2J1 | c.12C>T p.R4= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs779005860, COSV101470227; called by muse, varscan2
- VPS35 | c.1293G>A p.E431= | Silent (SNP) | VAF 15/164 reads (9%) | catalogued as COSV100140450; called by muse, mutect2
- VSIG8 | c.657G>A p.L219= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as COSV100928751; called by muse, mutect2, varscan2
- WDR24 | c.1521C>T p.I507= (on ENST00000248142; = p.I377= on NM_032259.4) | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV99555362; called by muse, mutect2, varscan2
- YLPM1 | c.1881T>C p.A627= | Silent (SNP) | VAF 23/135 reads (17%) | catalogued as COSV99458431; called by muse, mutect2, varscan2
- ZBTB8OS | c.96C>T p.I32= | Silent (SNP) | VAF 43/117 reads (37%) | catalogued as rs766166912, COSV100542136, COSV59385514; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1446C>G p.L482= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV99837415; called by muse, mutect2, varscan2
- ZNF189 | c.369G>A p.L123= | Silent (SNP) | VAF 12/165 reads (7%) | catalogued as COSV99407086; called by muse, mutect2
- ZNF234 | c.1563C>T p.F521= | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as COSV101468334; called by muse, mutect2, varscan2
- ZNF257 | c.744G>A p.K248= | Silent (SNP) | VAF 49/188 reads (26%) | catalogued as COSV71311075; called by muse, mutect2, varscan2
- ZNF490 | c.480G>A p.V160= | Silent (SNP) | VAF 70/273 reads (26%) | catalogued as COSV100267171, COSV61007885; called by muse, mutect2, varscan2
- ZNF572 | c.1173G>A p.K391= | Silent (SNP) | VAF 53/110 reads (48%) | catalogued as COSV100073791; called by muse, mutect2, varscan2
- ZXDC | c.504C>T p.S168= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs1405657346, COSV100306296; called by mutect2, varscan2
- CALCA | chr11:14967705 A>C | 3'Flank (SNP) | VAF 8/47 reads (17%) | catalogued as COSV100523909; called by muse, varscan2
- FBLN1 | c.1698-11399G>A | Intron (SNP) | VAF 25/76 reads (33%) | catalogued as rs11551; called by muse, mutect2, varscan2
- LEKR1 | c.*823G>A | 3'UTR (SNP) | VAF 38/266 reads (14%) | catalogued as COSV100738567; called by muse, mutect2, varscan2
- SLC25A3 | c.282+193G>T | Intron (SNP) | VAF 91/228 reads (40%) | catalogued as COSV99498964; called by muse, mutect2, varscan2
- ZNF467 | chr7:149777754 G>A | 5'Flank (SNP) | VAF 4/25 reads (16%) | catalogued as COSV100022129; called by mutect2, varscan2
